Somatic mutation profile of tumor specimen ALCH-AFA6-TTP1-A (aliquot ALCH-AFA6-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AFA6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.4 years (22,444 days).
Specimen ALCH-AFA6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 772ca0e7-7983-4e00-aa11-ca88caabe8be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFA6-NB1-A (Blood Derived Normal), aliquot ALCH-AFA6-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/300fcf8c-f7bc-498b-b1b2-20a8953d04b8

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCT | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 67/448 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1483748517; called by muse, mutect2, varscan2
- GPR6 | c.410C>A p.S137* | Nonsense Mutation (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- ZSWIM6 | c.816T>G p.C272W | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ERGIC2 | c.270A>G p.G90= | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- ZNF155 | c.129C>T p.N43= | Silent (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2
- VWDE | c.3745+1724T>A | Intron (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
